Somatic mutation profile of tumor specimen TCGA-2G-AAHT-01A (aliquot TCGA-2G-AAHT-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAHT, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 32.6 years (11,905 days).
Specimen TCGA-2G-AAHT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7698edc-07af-4770-82f1-7fad3c37b560.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHT-10A (Blood Derived Normal), aliquot TCGA-2G-AAHT-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84f6b4ce-c80b-4042-b5be-5f668fcb3b8c

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 1, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1671G>T p.W557C | Missense Mutation (SNP) | VAF 27/254 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55392798, COSV55404753, COSV55418401; called by muse, mutect2, varscan2
- CEBPZ | c.1791G>C p.Q597H | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs1423593898; called by muse, mutect2, varscan2
- PCDH10 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99992886; called by muse, mutect2, varscan2
- RASSF2 | c.760A>T p.I254F | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1568563253; called by muse, mutect2, varscan2
- ZNF491 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs1370116761; called by muse, mutect2, varscan2
- ELAVL4 | c.256_257del p.S86Ffs*7 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by pindel, varscan2
- ICOSLG | c.899-8C>A | Splice Region (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- PCDH10 | c.2462A>T p.Y821F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PRPF38B | c.990_992del p.S330del | In Frame Del (DEL) | VAF 39/168 reads (23%) | called by pindel, varscan2
- RC3H2 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UBE3C | c.2401T>C p.Y801H | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UBN1 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C1orf94 | c.33G>A p.L11= | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- CDH26 | c.763C>T p.L255= | Silent (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- RABL6 | c.42C>T p.A14= | Silent (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.79980G>A p.K26660= (on ENST00000591111; = p.K19236= on NM_003319.4) | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- RFX4 | c.44-7451G>A | Intron (SNP) | VAF 33/160 reads (21%) | catalogued as rs1280922062, COSV99075158; called by muse, mutect2, varscan2
